Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JH, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JH-01A (Primary Tumor).

[page 1 of 2]
Requesting Doctor's Information:

ICD-O-3

Carcinoma, adrenal cortical 8370/3

Site: (C) Adrenal Gland, cortex C74.0

QID 1/30/13

SPECIMEN TYPE: Adrenal Mass

CLINICAL NOTES:

17/40 pregnant; presented with LUQ pain + MRI shows 13cm mass with haemorrhage into left adrenal; normal urine, catecholamines, and mets; increased urinary free cortisol consistent with pregnancy; no clinical or clear biochemical evidence of hypersecretion. No family history. ?bleed into adenoma/ACC. ?non-secretory phaeo ?benign cystic adrenal.

Specimen received fresh for tumour banking. Sample frozen then formalin added.

MACROSCOPIC:

'Left adrenal cyst'. The specimen consists of an encapsulated tan nodule, 120 x 105 x 90mm, weighing 697g. There was focal disruption of the capsule on receipt, measuring up to 60 x 10mm across. The capsule is otherwise intact. The capsule inked green, is translucent and overlies a tan nodule with a bosselated surface. The cut surface of the lesion exhibits a large area of grey brown necrosis, which extends throughout the specimen at the periphery of which is haemorrhagic parenchyma. Attached focally to the capsule is normal appearing adrenal gland, 60 x 15 x 3mm. The lesion appears to be associated with the adrenal cortex, however, is separate from the cortex by a pale capsule up to 2mm in thickness. Representative sections embedded in 20 blocks.

Blocks 1-4: lesion with overlying normal adrenal

Blocks 5-20: representative sections of lesion

MICROSCOPIC:

The 697 gram adrenal tumour is a low grade oncocytic ADRENAL CORTICAL CARCINOMA. The tumour displays 4 of the 9 Weiss criteria for malignancy (eosinophilic cell type, cytological atypia, diffuse architecture and necrosis). There is no vascular space invasion, no capsular invasion, no sinusoidal invasion, no atypical mitoses and there is no significant mitotic activity (1 mitosis per 50 hpf). The presence of zonal necrosis (as well as coagulative necrosis) and recent intra-tumour haemorrhage account for the areas of softening identified grossly.

The tumour cells display oncocytic differentiation characterised by prominent granular eosinophilic cytoplasm. The tumour arises from the adrenal cortex and the adjacent non-neoplastic adrenal cortex and medulla is unremarkable. The tumour is surrounded by a capsule/pseudocapsule which separates it from the soft tissue resection margin. This capsule is delicate but intact indicating that local excision is complete albeit by a very slender margin (less than 0.1 mm across very broad fronts).

P
A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O

[page 2 of 2]
Requesting Doctor's Information:

HISTOPATHOLOGY

SPECIMEN TYPE: Adrenal Mass

Immunohistochemistry confirms adrenal cortical differentiation and is as follows:

MelanA: Positive

Calretinin: Focally positive

Chromogranin: Negative

IGF2: Focally positive (including some areas of perinuclear accumulation)

S-100/HMB45: Negative

Cytokeratin (AE1/AE3): Negative

Ki-67: Proliferative index less than 5%

COMMENT:

It has been demonstrated that oncocytic adrenocortical carcinomas have a better prognosis than other adrenal cortical carcinomas. This justifies the grading of this carcinoma as low grade. (Summarised in ref: Bisceglia M, Ludovico O, Di Mattia A et al Adrenocortical oncocytic tumours: Report of 10 cases and review on the literature International Journal of Surgical Pathology; July 2004; 13(3) 231-243).

SUMMARY:

Left adrenal gland: Low grade oncocytic adrenal cortical carcinoma 697 grams.

REPORTING PATHOLOGIST:

(Electronic Signature)

ANATOMICAL PATHOLOGY

HI/PA Discrepancy		

Page 2 of 2

Where 'Collected' indicates Rec:

No collection details given. Received details entered as collection details.

Source: NCI Genomic Data Commons file 2c1adf6c-ceb7-4112-8cd0-535545dd2674 (TCGA-OR-A5JH.CF498A30-11FC-4F20-A424-E3A1216D54B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).